Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA1W, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA1W-06A (Metastatic).

ICD-O-3

Melanoma NOS 8720/3

Site: Lymph nodes, peri-aortic C77.2

QW 4/2/14

CLINICAL HISTORY

Metastatic melanoma stage IV with periaortic lymph nodes.

GROSS DESCRIPTION

1. Labeled "right periaortic retrocaval lymph nodes": The specimen consists of an unoriented, focally disrupted 9.5 x 6 x 2 cm segment of soft to rubbery, tan and red tan tissue. Multiple nodules of rubbery firm, tan and purple tan tissue ranging up to 4 x 2 x 1.9 cm are found. Representative sections are submitted in 1A-1F.

2. Labeled "additional lymph nodes, periaortic, retrocaval": The specimen consists of four irregular fragments of soft and rubbery firm, yellow and red tan tissue ranging from 1.7 to 3.2 cm in greatest dimension and forming a 3.7 x 3.5 x 0.9 cm aggregate. Totally submitted in 2A-2B.

Microscopic sections are prepared and interpreted.

DIAGNOSIS

1. LABELED "RIGHT PERIAORTIC RETROCAVAL LYMPH NODES".
- METASTATIC MELANOMA INVOLVING MULTIPLE MATTED LYMPH NODES, 4.0 CM.
2. LABELED "ADDITIONAL LYMPH NODES, PERIAORTIC, RETROCAVAL".
- NO EVIDENCE OF METASTATIC MELANOMA IN FOUR LYMPH NODES EXAMINED (0/4).

Signed Electronically signed by:

** END OF REPORT **

Criteria	hw 12/19/13	Yes	No
Prior Malignancy History	Primary Melanoma	/	

Source: NCI Genomic Data Commons file 8e1dff4e-f86c-452c-aac0-d335371a50dd (TCGA-W3-AA1W.1DF225A2-C9D3-449B-BEAC-35A685E30A38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).